Somatic mutation profile of tumor specimen TCGA-EK-A2RD-01A (aliquot TCGA-EK-A2RD-01A-12D-A20U-09) from TCGA case TCGA-EK-A2RD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 47.1 years (17,191 days).
Specimen TCGA-EK-A2RD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ec70a4b-1752-4608-b35c-ec1cb128b5ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2RD-10A (Blood Derived Normal), aliquot TCGA-EK-A2RD-10A-01D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0051856-30a0-4e84-8441-6e3d7580d9b7

The open-access MAF lists 194 somatic variants for this specimen: 135 protein-altering or splice-affecting, 58 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 58, Nonsense Mutation 9, Splice Site 2, RNA 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO7A | c.5945G>A p.G1982E | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs111033250, CM091799, COSV68685675; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.2095G>A p.G699S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs142855321; called by muse, mutect2, varscan2
- ADGRF5 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV51932739; called by muse, mutect2, varscan2
- AHNAK | c.3150G>C p.L1050F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV99948991; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.4147C>G p.Q1383E | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV51852665; called by muse, mutect2, varscan2
- ANKIB1 | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV56063810; called by muse, mutect2, varscan2
- AP002748.5 | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs746824022, COSV59150295; called by muse, mutect2, varscan2
- AQR | c.2122C>T p.Q708* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as COSV99334452; called by muse, mutect2, varscan2
- ARHGAP6 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV57299032; called by muse, mutect2, varscan2
- ARL6IP1 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV100435967; called by muse, mutect2
- ATG3 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.201); catalogued as COSV51927549, COSV51928480; called by muse, mutect2, varscan2
- ATP2B4 | c.3238G>C p.D1080H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.937); catalogued as COSV58180392; called by muse, mutect2, varscan2
- BICD2 | c.2240G>A p.R747H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs878944571, COSV63549961; called by muse, mutect2, varscan2
- BMPR1B | c.1307C>G p.S436C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52779482; called by muse, mutect2, varscan2
- BMX | c.1068G>C p.E356D | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.579); catalogued as COSV59592238; called by muse, mutect2, varscan2
- C2orf73 | c.596C>G p.S199* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV58311381; called by muse, mutect2, varscan2
- CAVIN3 | c.581C>G p.S194W | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58269136, COSV58269396; called by muse, mutect2
- CCSAP | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52909933, COSV99497426; called by muse, mutect2, varscan2
- CD8A | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV52158478; called by muse, mutect2, varscan2
- CDKN2AIP | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV56627600; called by muse, mutect2, varscan2
- CEMIP | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV54996204; called by muse, mutect2, varscan2
- CERS4 | c.618C>G p.F206L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as COSV52168543; called by muse, mutect2, varscan2
- CHI3L1 | c.1114C>T p.L372F | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1558147270, COSV55139289; called by muse, mutect2
- CLCF1 | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV56862030; called by muse, mutect2, varscan2
- CMYA5 | c.6691G>A p.E2231K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.02); catalogued as COSV71407509; called by muse, mutect2, varscan2
- CSMD3 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52110518, COSV99033799; called by muse, mutect2, varscan2
- CTDP1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as COSV50005919; called by muse, mutect2, varscan2
- DCAF4L2 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs754087533, COSV60476314; called by muse, mutect2, varscan2
- DDX42 | c.2546G>A p.S849N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.025); catalogued as COSV63790673; called by mutect2, varscan2
- DENND3 | c.1379C>T p.S460L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.083); catalogued as rs770857480, COSV52804294; called by muse, varscan2
- DMD | c.7597G>A p.A2533T | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.284); catalogued as rs369583884, CD098168, COSV58896520; ClinVar: uncertain significance; called by mutect2, varscan2
- DOCK11 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs779867766, COSV52243406; called by muse, mutect2, varscan2
- DOCK5 | c.2829G>A p.M943I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV99377570; called by muse, mutect2, varscan2
- DOCK9 | c.4640C>G p.S1547C (on ENST00000376460 / NM_001366676.2; = p.S1548C on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100240594; called by muse, mutect2, varscan2
- DSCAM | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.361); catalogued as COSV68647001; called by muse, mutect2, varscan2
- EDEM3 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100545596; called by mutect2, varscan2
- EIF2B4 | c.895G>C p.E299Q (on ENST00000347454 / NM_001034116.2; = p.E298Q on NM_015636.3) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV52008921; called by muse, mutect2, varscan2
- ELOVL4 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs978619635, COSV63953867; called by muse, mutect2, varscan2
- ENPEP | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.355); catalogued as COSV54453834; called by muse, mutect2
- EZR | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as rs779204762, COSV51912606; called by muse, mutect2, varscan2
- FGA | c.2391G>C p.E797D | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as COSV57398213; called by muse, mutect2, varscan2
- FOCAD | c.1842G>C p.L614F | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100620125; called by muse, mutect2
- FRMD3 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.281); catalogued as COSV58464860; called by muse, mutect2, varscan2
- GABRA6 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as rs372922965; called by muse, mutect2, varscan2
- GGT7 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60541664; called by muse, mutect2, varscan2
- GLIS2 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV52111194; called by muse, mutect2
- GPC2 | c.1681C>T p.H561Y | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV52785722; called by muse, mutect2, varscan2
- HMGB1 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as COSV58105285; called by muse, mutect2, varscan2
- HOXB1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV53317103, COSV53317966; called by muse, mutect2, varscan2
- ICE2 | c.351G>C p.K117N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs1448939028, COSV55032471; called by muse, mutect2, varscan2
- IFT52 | c.117G>C p.Q39H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV65975532; called by muse, mutect2, varscan2
- IL18RAP | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV51827457; called by muse, mutect2, varscan2
- INAVA | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1164084143, COSV66257131; called by muse, mutect2, varscan2
- INHBA | c.419T>C p.I140T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV54223011; called by muse, mutect2, varscan2
- IQCN | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as COSV66575612; called by muse, mutect2, varscan2
- ITM2A | c.724G>C p.D242H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as COSV64811366; called by muse, mutect2, varscan2
- JUN | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64664709; called by muse, mutect2, varscan2
- KDM6A | c.2939-1G>A p.X980_splice | Splice Site (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100938585, COSV65042892; called by muse, mutect2
- KIF26A | c.2698C>G p.R900G | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as COSV59468268, COSV59468873; called by muse, mutect2
- KMT2C | c.8575C>T p.H2859Y | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs781083622, COSV51466390; called by muse, mutect2, varscan2
- KNTC1 | c.224G>C p.R75T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV61081873; called by muse, mutect2, varscan2
- LACTB | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.18); catalogued as COSV99979030; called by muse, mutect2, varscan2
- LAMA2 | c.3571G>T p.E1191* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV70344499, COSV70351713; called by muse, mutect2, varscan2
- LAMA3 | c.1699G>C p.D567H | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV58073060; called by muse, mutect2, varscan2
- LARP6 | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54581276; called by muse, varscan2
- LARP6 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV54581290; called by muse, mutect2, varscan2
- LRRIQ1 | c.4697C>T p.S1566L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs758802431, COSV67834090; called by muse, mutect2, varscan2
- MASP1 | c.1806G>A p.M602I | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.397); catalogued as COSV61828640; called by muse, mutect2, varscan2
- MAST3 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs748011253, COSV53223350; called by muse, mutect2, varscan2
- MED25 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs1266488266, COSV57205913; called by muse, mutect2, varscan2
- MNS1 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 48/112 reads (43%) | catalogued as COSV53069262; called by muse, mutect2
- NAT16 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.652); catalogued as rs746531603; called by muse, mutect2
- NEK1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.191); catalogued as COSV71457007; called by muse, mutect2, varscan2
- NF1 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV62193050; called by muse, mutect2, varscan2
- NIPSNAP1 | c.398C>G p.P133R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV53343249, COSV99331130; called by muse, varscan2
- NPY2R | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV61528895; called by muse, mutect2, varscan2
- NUP160 | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.277); catalogued as COSV65855051; called by muse, mutect2, varscan2
- NUPR1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs749422949, COSV61405154; called by mutect2, varscan2
- NYAP1 | c.2268G>A p.Q756= | Splice Region (SNP) | VAF 6/39 reads (15%) | catalogued as COSV55720318; called by muse, mutect2, varscan2
- OBSCN | c.11416G>C p.E3806Q | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.659); catalogued as COSV99482837; called by muse, mutect2
- OLFM4 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54577706, COSV54578618; called by muse, mutect2, varscan2
- PARP14 | c.3752C>T p.S1251L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as COSV71735133; called by muse, mutect2
- PCDH12 | c.2485C>G p.Q829E | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.428); catalogued as COSV51522767; called by muse, mutect2, varscan2
- PCDHGA2 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); catalogued as rs769248665, COSV53929048; called by muse, mutect2, varscan2
- PDHB | c.612G>C p.L204F | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV57057241; called by muse, mutect2
- PI4KA | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV55423110; called by muse, mutect2, varscan2
- PIKFYVE | c.6006C>G p.I2002M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52244884; called by muse, mutect2, varscan2
- PKD2L2 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV51799335; called by muse, mutect2, varscan2
- PLEC | c.10187C>G p.S3396C (on ENST00000322810 / NM_201380.4; = p.S3286C on NM_000445.5) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV59660464; called by muse, mutect2, varscan2
- PLEKHA6 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV55331056, COSV55334020; called by muse, mutect2, varscan2
- PMS1 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV59718014; called by muse, mutect2, varscan2
- PPM1B | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs202053989, COSV56768225; called by muse, mutect2, varscan2
- PUM2 | c.2946G>C p.Q982H | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.056); catalogued as COSV57583285; called by muse, mutect2, varscan2
- RBL2 | c.2347C>T p.Q783* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV50881917; called by muse, mutect2, varscan2
- RGS4 | c.150-1G>C p.X50_splice | Splice Site (SNP) | VAF 6/21 reads (29%) | catalogued as COSV63357749; called by muse, mutect2, varscan2
- RITA1 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as rs768035726, COSV55322221; called by muse, mutect2, varscan2
- ROCK1 | c.3904C>T p.Q1302* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV101296586; called by muse, mutect2, varscan2
- SLAMF1 | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV52500438; called by muse, mutect2, varscan2
- SLC41A1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as rs373421823, CM144608; called by muse, mutect2, varscan2
- SLITRK6 | c.2512G>C p.E838Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101233271, COSV68390847; called by muse, mutect2, varscan2
- SOCS3 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV58270928; called by muse, mutect2, varscan2
- SP140 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV59452233; called by muse, mutect2, varscan2
- SPATA31E1 | c.1218C>G p.F406L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.47); catalogued as COSV57791005, COSV57793443; called by muse, mutect2, varscan2
- ST18 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV52494308, COSV52511404; called by muse, mutect2, varscan2
- ST8SIA1 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs1317393088, COSV53956461; called by muse, mutect2, varscan2
- SYNM | c.3412G>C p.E1138Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782390681, COSV50442796; called by muse, mutect2, varscan2
- SYNM | c.3691G>A p.E1231K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as COSV50442799; called by muse, mutect2, varscan2
- TAF5L | c.1588A>G p.M530V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV51082119; called by muse, mutect2, varscan2
- THBS1 | c.79G>C p.D27H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV52953910; called by muse, mutect2, varscan2
- TICRR | c.2686C>T p.Q896* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as COSV51543936; called by muse, mutect2, varscan2
- TMEM161B | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV56932214; called by muse, mutect2, varscan2
- TMEM35A | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65863965; called by muse, mutect2, varscan2
- TPRG1 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.185); catalogued as COSV61466177; called by muse, mutect2, varscan2
- TRANK1 | c.5837C>T p.S1946L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV57156623; called by muse, mutect2, varscan2
- TRAPPC12 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.222); catalogued as COSV60847541; called by muse, mutect2, varscan2
- TRRAP | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV62849051, COSV62851611; called by muse, mutect2, varscan2
- TTN | c.23075C>G p.S7692C (on ENST00000591111; = p.S6765C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | PolyPhen possibly damaging (0.717); catalogued as COSV60185238; called by muse, mutect2, varscan2
- UGT2A1 | c.738G>C p.E246D | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV54144149; called by muse, mutect2, varscan2
- USP3 | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.14); catalogued as COSV99165780; called by muse, mutect2, varscan2
- VEZT | c.1531G>C p.E511Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as COSV54141562; called by mutect2, varscan2
- VPS13A | c.4788G>A p.M1596I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV62433136, COSV62436921; called by muse, mutect2, varscan2
- WDR3 | c.1172T>C p.L391S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV62524090; called by muse, mutect2, varscan2
- WDR7 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV54357919; called by muse, mutect2, varscan2
- ZBTB2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.055); catalogued as COSV57313356; called by muse, mutect2, varscan2
- ZFYVE19 | c.1240G>A p.E414K (on ENST00000355341 / NM_001077268.2; = p.E404K on NM_032850.5) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as COSV54541258; called by muse, mutect2, varscan2
- ZNF236 | c.4894G>A p.E1632K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV99469278; called by muse, mutect2, varscan2
- ZNF597 | c.213A>T p.E71D | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.202); catalogued as COSV57084916; called by muse, mutect2, varscan2
- ZNF611 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60542196; called by muse, mutect2, varscan2
- ZNF700 | c.1982C>T p.S661F | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54314077; called by muse, mutect2
- ZNF740 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.282); catalogued as COSV57243893; called by muse, mutect2, varscan2
- ZNF750 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 31/60 reads (52%) | catalogued as COSV53959823, COSV99489906; called by muse, mutect2, varscan2
- HPD | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.635); called by muse, mutect2
- LTN1 | c.1114C>G p.Q372E | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.037); called by muse, mutect2
- TRAV10 | c.127C>G p.Q43E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AGAP6 | c.1305G>A p.L435= (on ENST00000374056 / NM_001365867.1; = p.L458= on NM_001077665.2) | Silent (SNP) | VAF 27/148 reads (18%) | catalogued as COSV65018005; called by muse, mutect2, varscan2
- AHCTF1 | c.4557G>A p.L1519= (on ENST00000366508; = p.L1493= on NM_015446.5) | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV58252445; called by muse, mutect2, varscan2
- AP1M1 | c.1128C>A p.I376= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99358588; called by muse, mutect2, varscan2
- ASMT | c.978C>T p.F326= (on ENST00000381229; = p.F354= on NM_004043.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV101172513; called by muse, mutect2
- ATP1A3 | c.1305C>T p.V435= (on ENST00000545399 / NM_001256214.2; = p.V422= on NM_152296.5) | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as rs1568862347; called by muse, mutect2
- AXIN2 | c.1659G>A p.S553= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs967153637, COSV61058901; called by muse, mutect2, varscan2
- BSDC1 | c.786G>A p.E262= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV61982583; called by muse, mutect2, varscan2
- C16orf54 | c.309G>C p.L103= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV61477010; called by muse, mutect2
- CCNL2 | c.462G>C p.L154= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV61224421; called by muse, mutect2, varscan2
- CFAP70 | c.798C>T p.S266= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs375148315; called by muse, mutect2, varscan2
- DNAH11 | c.2862G>A p.E954= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV60966289; called by muse, mutect2, varscan2
- ECI1 | c.477G>C p.L159= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as COSV100066962; called by muse, mutect2, varscan2
- EIF2S3 | c.1389G>A p.V463= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV53407280; called by muse, mutect2, varscan2
- FANCB | c.1770C>T p.F590= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV60760885; called by muse, mutect2, varscan2
- FRRS1L | c.489C>T p.V163= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV73746729; called by muse, mutect2, varscan2
- FZD10 | c.792C>T p.I264= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV57474561; called by muse, mutect2, varscan2
- GDPD4 | c.1533G>A p.Q511= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV60020805; called by muse, mutect2, varscan2
- GRB2 | c.57C>T p.F19= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs1363030509, COSV100353561; called by muse, mutect2
- KCNA5 | c.1764C>G p.V588= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs1262924460, COSV52907321, COSV52908622; called by muse, mutect2
- KIAA1958 | c.1713G>A p.T571= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs150043037; called by muse, mutect2, varscan2
- L1CAM | c.597C>T p.L199= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV62828977; called by muse, mutect2, varscan2
- LARP6 | c.381G>A p.V127= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV54581262; called by muse, varscan2
- MACF1 | c.5539C>T p.L1847= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV99246209; called by muse, mutect2, varscan2
- MGAT4A | c.1008T>C p.P336= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV53848613; called by muse, mutect2, varscan2
- MRPL53 | c.108G>T p.T36= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs1032553544, COSV50688792; called by muse, mutect2, varscan2
- MSH5 | c.2247G>A p.A749= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs527749901, COSV100991944; called by muse, mutect2, varscan2
- MSN | c.675C>T p.L225= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100814287; called by muse, mutect2, varscan2
- MYBPC2 | c.2460C>T p.S820= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs376193301, COSV63094991; called by muse, mutect2, varscan2
- NDN | c.300G>A p.Q100= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1385480423, COSV59358687; called by muse, mutect2, varscan2
- NIPSNAP1 | c.576C>T p.L192= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV53342808, COSV99331288; called by muse, varscan2
- NIPSNAP1 | c.510C>T p.F170= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs1292373834, COSV99331291; called by muse, varscan2
- NPHP3 | c.1050C>T p.L350= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as COSV100447259; called by muse, mutect2, varscan2
- OCA2 | c.2202G>T p.L734= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV62351330; called by muse, mutect2, varscan2
- OR4X1 | c.621C>T p.V207= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV60723344; called by muse, mutect2, varscan2
- ORC1 | c.1221G>A p.E407= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV65364480; called by muse, mutect2, varscan2
- PAK4 | c.1686G>A p.T562= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs55747949; called by muse, mutect2, varscan2
- PCDHA1 | c.2100G>C p.L700= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV65375537; called by muse, mutect2, varscan2
- PCDHB12 | c.1419C>T p.I473= | Silent (SNP) | VAF 47/152 reads (31%) | catalogued as COSV53398742; called by muse, mutect2, varscan2
- PNOC | c.117C>T p.F39= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs368188580; called by muse, mutect2, varscan2
- PPP1CA | c.390C>A p.I130= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV56704049; called by muse, mutect2, varscan2
- PRDM11 | c.1011G>A p.L337= (on ENST00000530656 / NM_001359633.1; = p.L303= on NM_001256695.1) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV55440849, COSV55441633; called by muse, mutect2, varscan2
- PRR23B | c.531G>A p.G177= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV61494321; called by muse, mutect2, varscan2
- PTPRF | c.2025G>A p.E675= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV100741130; called by muse, mutect2, varscan2
- RICTOR | c.2454G>A p.L818= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV57125801; called by mutect2, varscan2
- SHFL | c.468G>A p.P156= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs772326880, COSV99463894; called by muse, mutect2, varscan2
- STRN | c.1902C>T p.F634= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as COSV55749801; called by muse, mutect2, varscan2
- TESMIN | c.1281C>T p.S427= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV99663897; called by muse, mutect2, varscan2
- TMEM171 | c.480C>T p.F160= | Silent (SNP) | VAF 20/154 reads (13%) | catalogued as COSV55131043; called by muse, mutect2, varscan2
- TNXB | c.219C>T p.F73= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV64483207; called by muse, mutect2, varscan2
- TYMP | c.639C>T p.L213= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs146557523; ClinVar: likely benign; called by muse, varscan2
- UQCRQ | c.201C>T p.F67= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV51526803; called by muse, mutect2, varscan2
- USP43 | c.1437C>A p.L479= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV53304673; called by mutect2, varscan2
- WDR13 | c.996C>T p.L332= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV54332605; called by muse, mutect2, varscan2
- WTIP | c.1206G>A p.A402= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs763860074, COSV54329328; called by muse, mutect2, varscan2
- ZNF492 | c.198G>A p.V66= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV71762164; called by muse, mutect2, varscan2
- ZNF778 | c.1338G>A p.E446= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV60601158, COSV60602134; called by muse, mutect2, varscan2
- ZP2 | c.273C>T p.I91= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV54815179; called by muse, mutect2, varscan2
- ZSWIM4 | c.1584C>T p.F528= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV54323958; called by muse, mutect2, varscan2
- TCP10L3 | n.2571C>T | RNA (SNP) | VAF 20/73 reads (27%) | catalogued as COSV64751819; called by muse, mutect2, varscan2
